Gene-level copy-number profile of tumor specimen C3N-03853-01 (profiled together with C3N-03853-02) from CPTAC case C3N-03853, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.2 years (17,976 days).
Specimen C3N-03853-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebae15ba-431d-4d7f-94c5-db481fc63372.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03853-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/2259e7de-f24e-4383-8329-f1dbeab75ad6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 2: 13,211; copy number 3: 5,760; copy number 4: 37,456; copy number 5: 950; copy number 6: 432; copy number 7: 55; copy number 8: 155; copy number 9: 86; copy number 10: 115; copy number 11: 16; copy number 14: 4; copy number 15: 18; copy number 17: 56.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–24,592,104, 80 genes (broad region; genes not listed).
- chr9:61,190,003–61,212,373, 4 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 295 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,350,934–39,576,790, 66 genes, copy number 9 (broad region; genes not listed).
- chr9:61,330,717–61,453,030, 2 genes, copy number 10: CNTNAP3C, RN7SL462P.
- chr10:32,446,140–32,882,874, 1 gene, copy number 11 (within-gene range 3–11): CCDC7.
- chr10:32,887,273–36,442,392, 53 genes, copy number 9–15: ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr18:22,088,060–34,224,952, 173 genes, copy number 10–17 (within-gene range 6–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
